Gene-level copy-number profile of tumor specimen HTMCP-02-03-01017-01A from CGCI case HTMCP-02-03-01017, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.8 years (21,829 days).
Specimen HTMCP-02-03-01017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68a352f5-73c1-40a4-9371-4cb8ac6e52f6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01017-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,253 have no estimate.
https://portal.gdc.cancer.gov/files/e28d4bf9-a7b1-4684-a17d-ed9e4a47773a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,047; copy number 2: 38,095; copy number 3: 4,269; copy number 4: 2,139; copy number 5: 710; copy number 6: 35; copy number 7: 32; copy number 8: 6; copy number 9: 7; copy number 10: 18; copy number 25: 3; copy number 41: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 820 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,911,553–121,398,806, 36 genes, copy number 5 (within-gene range 2–5): NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1.
- chr1:143,874,793–144,373,659, 15 genes, copy number 5–6: FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr1:145,095,974–145,287,755, 10 genes, copy number 5–9: FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1.
- chr1:145,407,772–145,408,173, 1 gene, copy number 5: PFN1P3.
- chr1:206,186,179–206,204,414, 1 gene, copy number 8 (within-gene range 2–8): FAM72A.
- chr1:222,477,252–222,519,732, 3 genes, copy number 6: AL513314.2, RNU6-791P, AL592148.2.
- chr2:113,588,550–113,627,090, 4 genes, copy number 6–7: WASH2P, DDX11L2, AL078621.1, RPL23AP7.
- chr3:122,909,082–123,028,605, 1 gene, copy number 6 (within-gene range 3–6): SEMA5B.
- chr4:51,843,000–69,250,815, 254 genes, copy number 5 (broad region; genes not listed).
- chr4:69,437,357–88,730,103, 329 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr5:175,906,939–176,126,959, 8 genes, copy number 5: AC138965.1, THOC3, THOC3-AS1, OR1X1P, AC139491.3, AC139491.1, FAM153B, AC139491.7.
- chr5:176,124,210–176,131,461, 1 gene, copy number 5: AC139491.4.
- chr5:178,006,348–178,086,529, 1 gene, copy number 5 (within-gene range 2–5): FAM153CP.
- chr7:63,699,390–63,700,441, 1 gene, copy number 6: AC079355.1.
- chr7:74,796,144–74,913,310, 5 genes, copy number 8: GTF2IRD2, STAG3L2, PMS2P5, Y_RNA, SPDYE12P.
- chr8:37,962,990–38,704,855, 30 genes, copy number 6–41: ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1.
- chr10:47,908,064–48,119,455, 8 genes, copy number 7: AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.
- chr14:37,197,913–37,552,361, 2 genes, copy number 7: MIPOL1, RNU6-886P.
- chr14:38,738,155–38,948,273, 1 gene, copy number 5 (within-gene range 4–5): LINC00639.
- chr14:38,973,399–40,390,547, 20 genes, copy number 5: AL132994.2, Y_RNA, SEC23A, AL109628.1, SEC23A-AS1, PPIAP4, GEMIN2, TRAPPC6B, AL109628.2, RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1.
- chr15:30,083,053–30,617,749, 37 genes, copy number 5 (within-gene range 2–5): GOLGA8J, RN7SL673P, DNM1P28, ULK4P3, U8, GOLGA8T, RN7SL469P, DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3, AC026150.2, AC026150.1, GOLGA8Q, RN7SL796P, DNM1P50, ULK4P2, U8, GOLGA8H, AC026150.3, RN7SL628P, AC091057.3.
- chr15:32,384,937–32,439,767, 6 genes, copy number 5–9: DNM1P31, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32.
- chr15:32,519,848–32,536,926, 1 gene, copy number 6 (within-gene range 3–6): AC135983.2.
- chr16:29,380,242–29,613,717, 16 genes, copy number 7 (within-gene range 4–7): AC025279.3, NPIPB11, SMG1P6, AC133555.6, BOLA2, BOLA2-SMG1P6, AC133555.4, SLX1B, SLX1B-SULT1A4, SULT1A4, AC133555.3, AC133555.5, AC133555.2, AC133555.1, NPIPB12, SMG1P2.
- chr16:33,802,764–34,013,830, 18 genes, copy number 10: IGHV3OR16-12, AC136428.3, IGHV3OR16-13, AC136428.1, AC140658.6, AC140658.7, AC140658.2, IGHV3OR16-11, AC140658.3, ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2.
- chr22:15,282,557–15,350,043, 5 genes, copy number 7: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.
- chr22:50,735,825–50,801,309, 6 genes, copy number 5: AC000036.1, ACR, AC002056.2, AC002056.1, RPL23AP82, RABL2B.

Autosomal genes at a single copy (total copy number 1): 12,227. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
